Somatic mutation profile of tumor specimen C3N-03851-01 (aliquot CPT0237200007) from CPTAC case C3N-03851, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 44.1 years (16,108 days).
Specimen C3N-03851-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 832e3ba8-622a-4940-a4e8-71382955ef65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03851-31 (Blood Derived Normal), aliquot CPT0237260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56542cb6-98d6-4d54-8f73-3dfb6dda50eb

The open-access MAF lists 648 somatic variants for this specimen: 437 protein-altering or splice-affecting, 125 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 363, Silent 125, Intron 44, Nonsense Mutation 26, Frame Shift Del 17, Splice Site 14, RNA 12, 3'UTR 12, 5'UTR 11, Frame Shift Ins 8, Splice Region 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 136/406 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- A1BG | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs1282842989; called by muse, mutect2, varscan2
- ABCA8 | c.3919G>T p.V1307L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757311797; called by muse, mutect2, varscan2
- ABCG8 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55395072; called by muse, mutect2, varscan2
- ADAMTS13 | c.4000C>A p.H1334N | Missense Mutation (SNP) | VAF 131/433 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1281020165; called by muse, mutect2, varscan2
- ADAMTSL3 | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 90/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99722166; called by muse, varscan2
- ADAMTSL3 | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54442020; called by muse, varscan2
- AGPS | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM120345, COSV51562386; called by muse, mutect2, varscan2
- AHNAK | c.4716G>A p.M1572I | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV99949899; called by muse, mutect2, varscan2
- AL592490.1 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV69427716; called by muse, mutect2, varscan2
- ANKIB1 | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs764459051; called by muse, mutect2, varscan2
- APOO | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV64870732; called by muse, mutect2, varscan2
- ARHGAP22 | c.1737C>A p.N579K | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1248518555; called by muse, mutect2, varscan2
- ATG2A | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 228/1001 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs777723818, COSV65965767; called by muse, mutect2, varscan2
- AXDND1 | c.1365G>T p.L455F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100858270; called by muse, mutect2, varscan2
- BAZ1B | c.1311G>C p.Q437H | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59990391; called by muse, mutect2
- BCL2L13 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as COSV58225357; called by muse, mutect2, varscan2
- BIRC6 | c.11816G>A p.R3939K | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.856); catalogued as rs553403645, COSV101427757; called by muse, mutect2, varscan2
- BOC | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs1486473030; called by muse, mutect2, varscan2
- C10orf120 | c.7A>G p.R3G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs761185660; called by muse, mutect2, varscan2
- C16orf90 | c.364C>A p.R122S (on ENST00000399645 / NM_001353385.2; = p.R113S on NM_001080524.2) | Missense Mutation (SNP) | VAF 136/544 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs540246037; called by muse, mutect2, varscan2
- CACNA1E | c.4736G>T p.R1579L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62414608; called by muse, mutect2, varscan2
- CACNG7 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV55815583; called by muse, varscan2
- CAND1 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 33/64 reads (52%) | catalogued as COSV73389605; called by muse, mutect2, varscan2
- CAPG | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 150/503 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs757065726; called by muse, mutect2, varscan2
- CAPN13 | c.360C>G p.H120Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs764710395; called by muse, mutect2, varscan2
- CCSER1 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs775741786, COSV100388301, COSV100390100; called by muse, mutect2, varscan2
- CD163L1 | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 210/319 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99047110; called by muse, mutect2, varscan2
- CFHR4 | c.1385C>A p.P462H (on ENST00000367416 / NM_001201551.2; = p.P216H on NM_006684.5) | Missense Mutation (SNP) | VAF 86/539 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs755969228, COSV52229180; called by muse, mutect2, varscan2
- CNTN2 | c.2377C>A p.R793S | Missense Mutation (SNP) | VAF 142/492 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1477916385, COSV59349128; called by muse, mutect2, varscan2
- COL22A1 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1339309219; called by muse, mutect2, varscan2
- COL6A5 | c.6644C>A p.S2215Y (on ENST00000312481; = p.S2211Y on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV55206226; called by muse, mutect2, varscan2
- CRIPT | c.201A>T p.Q67H | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs140621301; called by muse, mutect2, varscan2
- CRTAC1 | c.1797C>A p.N599K | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); catalogued as rs372101559; called by muse, mutect2, varscan2
- CSMD1 | c.6027C>G p.I2009M (on ENST00000520002; = p.I2008M on NM_033225.6) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs754224272, COSV59299270; called by muse, mutect2, varscan2
- CSMD2 | c.1228C>G p.R410G | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53891554; called by muse, mutect2, varscan2
- CSNK2A1 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424673; called by muse, mutect2, varscan2
- CSNK2A1 | c.717T>A p.Y239* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as COSV53937842; called by muse, mutect2, varscan2
- CTTN | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57236819; called by muse, mutect2, varscan2
- DAB2 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57917908; called by muse, mutect2, varscan2
- DAB2IP | c.2443G>T p.G815C (on ENST00000408936; = p.G787C on NM_032552.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs755018805; called by muse, mutect2, varscan2
- DDIAS | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV61272779; called by muse, mutect2, varscan2
- DENND1C | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 159/362 reads (44%) | catalogued as COSV100375156, COSV100375200; called by muse, mutect2, varscan2
- E4F1 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs1156291356; called by muse, mutect2, varscan2
- EYA2 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV57949099; called by muse, mutect2, varscan2
- EYS | c.2188T>C p.C730R | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1360679420; called by muse, mutect2, varscan2
- FAM83E | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54371900; called by muse, mutect2, varscan2
- FEZF1 | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 142/803 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV58659865; called by muse, mutect2, varscan2
- FEZF2 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 141/564 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs761222668; called by muse, mutect2, varscan2
- FIP1L1 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV60997811; called by muse, mutect2, varscan2
- FOXD4L1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 161/638 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs577424608; called by muse, mutect2, varscan2
- FRS2 | c.119T>G p.L40R | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100165975, COSV54723228; called by muse, mutect2, varscan2
- GIMAP7 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs748612836, COSV57958762; called by muse, mutect2
- GLP1R | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64715269; called by muse, mutect2, varscan2
- GNGT2 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55929836, COSV99865368; called by muse, mutect2, varscan2
- GRM5 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.217); catalogued as COSV100554145; called by muse, mutect2, varscan2
- GRSF1 | c.1000G>C p.G334R | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV54655174; called by muse, mutect2, varscan2
- HBB | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs281864514; called by muse, mutect2, varscan2
- HMCN1 | c.9617G>A p.G3206D | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54889173; called by muse, mutect2, varscan2
- HTR3A | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100248592; called by muse, mutect2, varscan2
- IL1B | c.455T>C p.M152T | Missense Mutation (SNP) | VAF 45/439 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs778331869; called by muse, mutect2
- IL33 | c.220A>T p.R74* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV67343178; called by muse, mutect2
- KCND2 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 166/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867482829, COSV100477119; called by muse, mutect2, varscan2
- KCNG2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs776506547; called by muse, mutect2, varscan2
- KNDC1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1439545846, COSV58830948; called by muse, mutect2, varscan2
- KRTAP10-12 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 155/1201 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV100554717, COSV100555019; called by muse, mutect2, varscan2
- KRTAP10-4 | c.672C>G p.C224W | Missense Mutation (SNP) | VAF 461/1320 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59972344; called by muse, mutect2, varscan2
- KRTAP13-3 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1324693957; called by muse, mutect2, varscan2
- KRTAP19-5 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 43/1000 reads (4%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.59); catalogued as rs1267943800; called by muse, mutect2
- LILRB4 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1292162910; called by muse, mutect2, varscan2
- LRRTM3 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.121); catalogued as COSV63663601, COSV63669725; called by muse, mutect2, varscan2
- MDGA2 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as rs927426048; called by muse, mutect2, varscan2
- MRC1 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781920426, COSV53471342; called by muse, mutect2, varscan2
- MROH2B | c.2886C>G p.G962= | Splice Region (SNP) | VAF 41/107 reads (38%) | catalogued as COSV68183311; called by muse, mutect2, varscan2
- MS4A1 | c.573+1G>T p.X191_splice | Splice Site (SNP) | VAF 56/208 reads (27%) | catalogued as rs1350279662; called by muse, mutect2, varscan2
- MS4A6E | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV55727384; called by muse, mutect2
- MUC6 | c.140C>G p.T47R | Missense Mutation (SNP) | VAF 110/196 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1026161249; called by muse, mutect2, varscan2
- MYH13 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747286137, COSV52829934; called by muse, mutect2, varscan2
- MYH4 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 123/598 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as rs1268421786, COSV55117418; called by muse, mutect2, varscan2
- MYO1F | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 99/183 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV57799774; called by muse, mutect2, varscan2
- NCOR2 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs561193208; called by muse, mutect2, varscan2
- NELL1 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV54237631; called by muse, mutect2, varscan2
- NGDN | c.12+1G>C p.X4_splice | Splice Site (SNP) | VAF 45/197 reads (23%) | catalogued as rs1363964306; called by muse, mutect2, varscan2
- NIP7 | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs548728135; called by muse, mutect2, varscan2
- NPHS1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV100800366; called by muse, mutect2, varscan2
- NRAP | c.1589C>T p.P530L (on ENST00000359988 / NM_001322945.2; = p.P495L on NM_006175.4) | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249689730; called by muse, mutect2
- NT5E | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57627290; called by muse, mutect2, varscan2
- NTRK1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1480681042, COSV62326687; called by muse, mutect2
- OR2M4 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100141101, COSV60708152; called by muse, mutect2, varscan2
- OR2T35 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1384618670; called by muse, mutect2, varscan2
- OR4C16 | c.72A>G p.I24M | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV58942972; called by muse, mutect2, varscan2
- OR5F1 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV53549135; called by muse, mutect2, varscan2
- OR6P1 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 210/753 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1168155054, COSV100583411; called by muse, mutect2, varscan2
- PCDHA12 | c.1617C>A p.D539E | Missense Mutation (SNP) | VAF 444/870 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100247546; called by muse, mutect2, varscan2
- PCDHA5 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 390/806 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100972517; called by muse, mutect2, varscan2
- PCDHB7 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.309); catalogued as rs1554280107, COSV50753829; called by muse, mutect2, varscan2
- PDZD2 | c.6421A>G p.T2141A | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV56849709; called by muse, mutect2, varscan2
- PFKP | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 33/112 reads (29%) | catalogued as COSV66895055; called by muse, mutect2, varscan2
- PIK3C2G | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV56838724; called by muse, mutect2, varscan2
- PIK3R5 | c.2510C>G p.P837R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV52653231; called by muse, mutect2, varscan2
- PLA2G2F | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs202089729, COSV100907933; called by muse, mutect2, varscan2
- PNPLA2 | c.1319A>C p.Q440P | Missense Mutation (SNP) | VAF 145/483 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs1319276173; called by muse, mutect2, varscan2
- PPFIA2 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100333610; called by muse, mutect2, varscan2
- PPM1D | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV59957546; called by muse, mutect2, varscan2
- PPP1R8 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.027); catalogued as rs1391534445; called by muse, mutect2, varscan2
- PRAMEF4 | c.1351A>T p.K451* | Nonsense Mutation (SNP) | VAF 119/484 reads (25%) | catalogued as rs1307989719; called by muse, mutect2, varscan2
- PTDSS1 | c.272-2A>T p.X91_splice | Splice Site (SNP) | VAF 27/125 reads (22%) | catalogued as COSV100428778; called by muse, mutect2, varscan2
- RGSL1 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54257247; called by muse, mutect2, varscan2
- RTN1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99957023; called by muse, mutect2, varscan2
- SCFD2 | c.1313G>T p.S438I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV66373241; called by muse, mutect2, varscan2
- SERPING1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 163/921 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs771637963, CD087110; called by muse, mutect2, varscan2
- SLC17A7 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV55548495; called by muse, mutect2, varscan2
- SLC40A1 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1328696186, CM083844; called by muse, mutect2, varscan2
- SMO | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV50839648; called by muse, mutect2, varscan2
- STING1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs775712223, COSV58173486; called by muse, mutect2, varscan2
- SYT12 | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67354095; called by muse, mutect2, varscan2
- TANC2 | c.5117G>A p.R1706Q | Missense Mutation (SNP) | VAF 140/327 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); catalogued as rs760022382; called by muse, mutect2, varscan2
- TCHH | c.1145A>T p.Q382L | Missense Mutation (SNP) | VAF 104/668 reads (16%) | PolyPhen benign (0.05); catalogued as COSV64275605; called by muse, varscan2
- TEKT5 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51586920; called by muse, mutect2, varscan2
- TENT4B | c.226C>T p.P76S (on ENST00000561678 / NM_001365323.2; = p.P61S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1279713309; called by muse, mutect2, varscan2
- TFAP2D | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); catalogued as COSV50429682; called by muse, mutect2, varscan2
- TIE1 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.94); catalogued as COSV100991958; called by muse, mutect2
- TMC1 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV52774183; called by muse, mutect2, varscan2
- TMEM184B | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as rs929603856; called by muse, mutect2, varscan2
- TP53 | c.720T>G p.S240R | Missense Mutation (SNP) | VAF 89/426 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764342812, COSV52783209, COSV52795438, COSV52891634, COSV53135249; ClinVar: uncertain significance; called by muse, varscan2
- UNC80 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 26/260 reads (10%) | catalogued as COSV55904593; called by muse, mutect2
- USH2A | c.2809+1G>T p.X937_splice | Splice Site (SNP) | VAF 32/138 reads (23%) | catalogued as rs759433119, CS149935; called by muse, mutect2, varscan2
- VIPR2 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs913955061; called by muse, mutect2, varscan2
- ZFHX4 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as COSV51484597; called by muse, mutect2, varscan2
- ZFHX4 | c.5048C>A p.P1683H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV51509010; called by muse, mutect2, varscan2
- ZNF469 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs865907429; called by muse, mutect2, varscan2
- ZNF716 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs1554324641, COSV70783072; called by muse, mutect2, varscan2
- ZNF766 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1348873303; called by muse, mutect2, varscan2
- ZP2 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV54812757; called by muse, mutect2, varscan2
- ABCG4 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ABHD10 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADSB | c.1228+1G>T p.X410_splice | Splice Site (SNP) | VAF 129/418 reads (31%) | called by muse, mutect2, varscan2
- ACSM5 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- ACVR2B | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 154/502 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by mutect2, varscan2
- ADAM29 | c.2274G>C p.Q758H | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ADAMTS16 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADCYAP1 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.1312-1G>A p.X438_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- ADGRE1 | c.833C>A p.T278N | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- AFTPH | c.1727A>C p.E576A | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- AGAP1 | c.1919del p.G640Efs*37 (on ENST00000304032 / NM_001037131.3; = p.G587Efs*37 on NM_014914.5) | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- AHCY | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 224/566 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AJAP1 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- AKAP9 | c.11489-3_11507del p.X3830_splice (on ENST00000359028; = p.X3806_splice on NM_005751.5 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 37/198 reads (19%) | called by mutect2, pindel, varscan2
- AL445989.1 | c.65_66insCTGCTATGGCTGTGGCTATGGCTC p.S22_G23insCYGCGYGS | In Frame Ins (INS) | VAF 68/181 reads (38%) | called by muse*, mutect2, varscan2*
- ALS2 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- AMELX | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 103/298 reads (35%) | called by muse, mutect2, varscan2
- ANGPT4 | c.1158A>T p.E386D | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANKRD30A | c.3010T>C p.S1004P (on ENST00000611781; = p.S948P on NM_052997.2) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ANKRD62 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- AP3B2 | c.3151G>T p.V1051F (on ENST00000261722; = p.V1045F on NM_004644.5) | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- APOB | c.13652A>T p.Y4551F | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APOB | c.11645C>T p.A3882V | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ARHGAP18 | c.120A>T p.R40S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF17 | c.2804G>T p.R935L | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASB10 | c.1013C>A p.P338Q (on ENST00000420175 / NM_001142459.2; = p.P323Q on NM_080871.4) | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- ASGR2 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ATP1A3 | c.2098C>G p.Q700E (on ENST00000545399 / NM_001256214.2; = p.Q687E on NM_152296.5) | Missense Mutation (SNP) | VAF 237/549 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAT1 | c.365_366del p.R122Lfs*11 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | called by mutect2, pindel, varscan2
- BEX1 | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 152/231 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3526G>A p.E1176K | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BNC2 | c.2127C>A p.D709E | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.054); called by muse, mutect2
- BRINP1 | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- C1orf94 | c.1783G>T p.G595C (on ENST00000488417 / NM_001134734.2; = p.G405C on NM_032884.5) | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6orf118 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CACNG3 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.089); called by muse, varscan2
- CACNG7 | c.385A>T p.I129F | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.843); called by muse, varscan2
- CASP12 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC160 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CCDC171 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC174 | c.1175dup p.P393Afs*28 | Frame Shift Ins (INS) | VAF 61/253 reads (24%) | called by mutect2, pindel, varscan2
- CCDC73 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC83 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CCNP | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 197/477 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CDH22 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 45/249 reads (18%) | called by muse, mutect2, varscan2
- CDK11B | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 149/489 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- CDX2 | c.484C>G p.R162G | Missense Mutation (SNP) | VAF 97/158 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- CELSR1 | c.1763A>T p.Q588L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP112 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHMP7 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CKAP2 | c.196C>T p.Q66* (on ENST00000378037 / NM_001098525.2; = p.Q65* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- CLASP2 | c.1108T>A p.L370M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCNKB | c.1805C>G p.A602G | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CLIP2 | c.2642T>A p.L881Q | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLK2 | c.416G>T p.R139I (on ENST00000368361 / NM_001294339.2; = p.R138I on NM_003993.4) | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CLK4 | c.905A>T p.K302I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CLNK | c.944G>T p.S315I | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CNTN4 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTN6 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- COG1 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL22A1 | c.2329G>T p.G777C | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLQ | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 143/474 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COX6A2 | c.73+8G>T | Splice Region (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- CPD | c.2957A>T p.K986M | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPS1 | c.2831T>C p.I944T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CRB2 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CROCC2 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRTC1 | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 199/419 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CSMD2 | c.2661_2662del p.L888Gfs*6 | Frame Shift Del (DEL) | VAF 42/290 reads (14%) | called by pindel, varscan2
- CUBN | c.10759G>T p.G3587* | Nonsense Mutation (SNP) | VAF 63/359 reads (18%) | called by muse, mutect2, varscan2
- CUBN | c.9416C>A p.T3139K | Missense Mutation (SNP) | VAF 94/408 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CUBN | c.7825G>T p.G2609* | Nonsense Mutation (SNP) | VAF 83/383 reads (22%) | called by muse, mutect2, varscan2
- CUTA | c.42+3G>T | Splice Region (SNP) | VAF 73/233 reads (31%) | called by muse, mutect2, varscan2
- DBF4B | c.1090del p.C364Vfs*24 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- DCD | c.289+1G>T p.X97_splice | Splice Site (SNP) | VAF 104/187 reads (56%) | called by muse, mutect2, varscan2
- DDI1 | c.763T>A p.L255M | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- DENND4C | c.2777G>A p.S926N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHX35 | c.1582A>T p.K528* | Nonsense Mutation (SNP) | VAF 69/160 reads (43%) | called by muse, mutect2, varscan2
- DIDO1 | c.514dup p.R172Pfs*7 | Frame Shift Ins (INS) | VAF 76/406 reads (19%) | called by mutect2, pindel, varscan2
- DISP1 | c.3321G>C p.Q1107H | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DKKL1 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLAT | c.1159A>T p.K387* | Nonsense Mutation (SNP) | VAF 96/419 reads (23%) | called by muse, mutect2, varscan2
- DLX6 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- DMBT1 | c.2330G>T p.G777V | Missense Mutation (SNP) | VAF 232/916 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMD | c.6615G>T p.R2205S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- DMRT2 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.898G>C p.A300P (on ENST00000409039; = p.A239P on NM_207437.3) | Missense Mutation (SNP) | VAF 147/274 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DNAH9 | c.11044del p.A3682Pfs*8 | Frame Shift Del (DEL) | VAF 39/229 reads (17%) | called by mutect2, pindel, varscan2
- DNAJC7 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNMBP | c.4048C>A p.R1350S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DOCK1 | c.2519G>T p.C840F | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DOCK8 | c.5962-2A>T p.X1988_splice | Splice Site (SNP) | VAF 40/146 reads (27%) | called by muse, mutect2, varscan2
- DRD1 | c.767C>G p.P256R | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DSG4 | c.153G>C p.W51C | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.18469A>T p.M6157L (on ENST00000361203 / NM_001374722.1; = p.M3854L on NM_015548.5) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ECH1 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGR1 | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.121); called by muse, varscan2
- ERN2 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 103/354 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FAM135A | c.4384G>T p.V1462F (on ENST00000370479 / NM_001351599.1; = p.V1249F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- FAM149A | c.1550G>T p.G517V (on ENST00000356371 / NM_001367768.2; = p.G226V on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- FAM181B | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FAM187A | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.053); called by muse, mutect2
- FAM71E2 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- FLAD1 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.019); called by muse, mutect2
- FLT1 | c.1680T>A p.H560Q | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FSCB | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FYB1 | c.2302G>T p.G768* (on ENST00000351578 / NM_199335.5; = p.G814* on NM_001465.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- GALNT13 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJC2 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 178/559 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GOLGA8O | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- GPA33 | c.307A>C p.T103P | Missense Mutation (SNP) | VAF 124/435 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GPATCH8 | c.3018G>T p.R1006S | Missense Mutation (SNP) | VAF 170/427 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- GPR52 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR62 | c.543C>A p.F181L | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIA4 | c.1807del p.L603Wfs*44 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel
- GRIN3B | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HERC2 | c.9494C>A p.T3165N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HGH1 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- HJURP | c.1813A>G p.I605V | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPF | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HNRNPM | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HOXC12 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 259/557 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HSPA1B | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 222/920 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HYDIN | c.2138A>G p.K713R | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ICAM4 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 256/489 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IFNGR1 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- IGHA1 | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL16 | c.2417C>G p.P806R (on ENST00000302987 / NM_172217.5; = p.P105R on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 109/186 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL1RL2 | c.1441dup p.M481Nfs*7 | Frame Shift Ins (INS) | VAF 27/285 reads (9%) | called by mutect2, pindel
- IMPDH1 | c.1437-1G>A p.X479_splice (on ENST00000470772 / NM_001142573.2; = p.X565_splice on NM_000883.4) | Splice Site (SNP) | VAF 144/589 reads (24%) | called by muse, mutect2, varscan2
- IMPDH1 | c.142G>T p.E48* (on ENST00000470772 / NM_001142573.2; = p.E133* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 109/392 reads (28%) | called by muse, mutect2, varscan2
- INVS | c.2857T>A p.W953R | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ITIH1 | c.1540C>A p.R514S | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KCNU1 | c.2274C>G p.D758E | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KIN | c.600del p.E201Rfs*7 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 154/411 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KLF11 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KLHDC4 | c.1072A>G p.R358G | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- KRT14 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 97/475 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP5-7 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 152/768 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LIN9 | c.1151A>T p.D384V (on ENST00000366808 / NM_001270410.2; = p.D329V on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LMO7 | c.1610del p.L537Yfs*18 (on ENST00000357063; = p.L267Yfs*18 on NM_015842.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | called by pindel, varscan2
- LPA | c.2467G>A p.V823M | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.324); called by muse, varscan2
- LRFN2 | c.1703T>A p.M568K | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC7 | c.782del p.P261Lfs*4 (on ENST00000651989 / NM_001370785.2; = p.P228Lfs*4 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 64/181 reads (35%) | called by mutect2, pindel, varscan2
- MACC1 | c.831A>T p.L277F | Missense Mutation (SNP) | VAF 110/393 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAPK7 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 48/251 reads (19%) | called by muse, mutect2, varscan2
- MARCHF6 | c.1459T>C p.F487L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MBTPS1 | c.1217G>C p.G406A | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MC3R | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF6 | c.4211G>T p.G1404V | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MEIS2 | c.901-21_908del p.X301_splice (on ENST00000561208 / NM_170675.5; = p.X288_splice on NM_002399.3) | Splice Site (DEL) | VAF 20/174 reads (11%) | called by mutect2, pindel
- MGAM | c.4117G>T p.V1373L | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MGAT4A | c.727T>C p.C243R | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2
- MIB2 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOB4 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- MORC1 | c.2341A>G p.M781V | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP7 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MPPE1 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MSANTD3 | c.656A>C p.H219P | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MUC16 | c.43353del p.F14452Sfs*19 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by pindel, varscan2*
- MUC4 | c.7291A>T p.T2431S | Missense Mutation (SNP) | VAF 123/1196 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.301); called by muse, mutect2
- MYH2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 85/500 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MYO3A | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2
- MYO6 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 105/641 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO6 | c.450_458del p.E152_G154del | In Frame Del (DEL) | VAF 47/300 reads (16%) | called by mutect2, pindel, varscan2
- MYOC | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 132/458 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NCKAP1 | c.2023C>T p.L675F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- NDST1 | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NEB | c.9976A>G p.K3326E | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NFAT5 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NFKBIE | c.739C>T p.Q247* (on ENST00000275015; = p.Q108* on NM_004556.3) | Nonsense Mutation (SNP) | VAF 105/567 reads (19%) | called by muse, mutect2, varscan2
- NFU1 | c.529T>A p.L177I (on ENST00000410022 / NM_001002755.4; = p.L153I on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NMUR2 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOL9 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- NR2E1 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- NRCAM | c.3639G>T p.Q1213H (on ENST00000379028 / NM_001371124.1; = p.Q1092H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NTRK3 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- NUP93 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OR11H12 | c.389T>C p.L130S | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR2B11 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- OR6F1 | c.434C>G p.A145G | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR9I1 | c.798A>T p.K266N | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- OSBPL11 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PADI4 | c.374del p.G125Afs*3 | Frame Shift Del (DEL) | VAF 43/274 reads (16%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.5014G>T p.G1672W | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCDH9 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCYT2 | c.430dup p.V144Gfs*26 | Frame Shift Ins (INS) | VAF 66/222 reads (30%) | called by mutect2, pindel, varscan2
- PDE1C | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZRN4 | c.2186A>C p.E729A (on ENST00000402685 / NM_001164595.2; = p.E471A on NM_013377.4) | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PGAP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/140 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PIEZO1 | c.6562T>G p.W2188G | Missense Mutation (SNP) | VAF 108/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIEZO2 | c.6191G>T p.R2064M | Missense Mutation (SNP) | VAF 146/404 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PIEZO2 | c.3982C>A p.L1328M | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PIGS | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C3 | c.1265G>T p.S422I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PIK3R6 | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIP5K1C | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 154/298 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PKNOX2 | c.731A>T p.Y244F | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PLCL1 | c.2927A>T p.Q976L | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLCXD1 | c.953A>C p.Q318P | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PLEC | c.13540G>T p.G4514C (on ENST00000322810 / NM_201380.4; = p.G4404C on NM_000445.5) | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG2 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLRG1 | c.618G>A p.W206* | Nonsense Mutation (SNP) | VAF 32/194 reads (16%) | called by muse, mutect2, varscan2
- POU2AF1 | c.744C>A p.N248K | Missense Mutation (SNP) | VAF 187/489 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PPARG | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R14D | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PPP1R15A | c.1709G>A p.W570* | Nonsense Mutation (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- PPP3CA | c.1433G>C p.R478P | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PPP6R1 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PRDM4 | c.1181_1182dup p.T395* | Frame Shift Ins (INS) | VAF 27/142 reads (19%) | called by mutect2, pindel, varscan2
- PRKCB | c.349C>A p.H117N | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRKDC | c.3829G>T p.G1277* | Nonsense Mutation (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- PRSS21 | c.258-1G>A p.X86_splice | Splice Site (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- PSMA8 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PSME4 | c.5020T>C p.F1674L | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- PTGER2 | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN4 | c.762A>T p.P254= | Splice Region (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- PZP | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RAPGEF5 | c.1460A>T p.K487I (on ENST00000401957 / NM_001367602.2; = p.K790I on NM_012294.5) | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- RELN | c.10183dup p.E3395Gfs*22 | Frame Shift Ins (INS) | VAF 121/405 reads (30%) | called by mutect2, pindel, varscan2
- RFPL2 | c.1084T>A p.L362M | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, varscan2
- ROBO1 | c.4544A>G p.D1515G | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ROBO2 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 155/486 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ROCK1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RSPRY1 | c.1017G>C p.E339D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- RXFP2 | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SALL2 | c.1636del p.T546Lfs*5 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel*, varscan2
- SAMD9 | c.3038C>A p.T1013N | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SBF1 | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SBSN | c.996T>G p.F332L | Missense Mutation (SNP) | VAF 57/452 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, varscan2
- SCML1 | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SCOC | c.57G>C p.M19I | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6B | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SFMBT2 | c.2509G>T p.D837Y | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SHANK3 | c.4348G>T p.A1450S | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SHPRH | c.4726C>T p.Q1576* (on ENST00000275233 / NM_001042683.3; = p.Q1580* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.2913G>C p.E971D | Missense Mutation (SNP) | VAF 270/446 reads (61%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SKOR1 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 260/611 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC12A3 | c.1188C>G p.C396W | Missense Mutation (SNP) | VAF 159/548 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC12A4 | c.503C>A p.A168D | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SLC16A14 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.421); called by muse, mutect2
- SLC20A1 | c.1916A>T p.K639M | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC37A3 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC4A5 | c.310dup p.E104Gfs*4 | Frame Shift Ins (INS) | VAF 22/232 reads (9%) | called by mutect2, pindel
- SLC6A19 | c.1702-2A>T p.X568_splice | Splice Site (SNP) | VAF 266/627 reads (42%) | called by muse, mutect2, varscan2
- SOGA3 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX9 | c.87C>A p.D29E | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- SP8 | c.717del p.L240Sfs*19 (on ENST00000361443 / NM_198956.4; = p.L258Sfs*19 on NM_182700.6) | Frame Shift Del (DEL) | VAF 64/182 reads (35%) | called by mutect2, varscan2
- SPN | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPTBN1 | c.2830G>T p.V944F | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SPTBN4 | c.5955G>C p.Q1985H | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SSH1 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYTL1 | c.526C>G p.Q176E (on ENST00000543823; = p.Q164E on NM_032872.3) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYTL1 | c.1399C>A p.R467S (on ENST00000543823; = p.R455S on NM_032872.3) | Missense Mutation (SNP) | VAF 98/372 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TAF1L | c.4913G>T p.C1638F | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TBCK | c.2173G>A p.G725R (on ENST00000273980 / NM_001163436.4; = p.G662R on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- TCHH | c.2334G>C p.E778D | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- THAP7 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 293/512 reads (57%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TIAM1 | c.419_420dup p.Y141Hfs*49 | Frame Shift Ins (INS) | VAF 117/570 reads (21%) | called by mutect2, pindel, varscan2
- TIE1 | c.2069C>A p.P690Q | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.959); called by muse, mutect2
- TIMP4 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 174/632 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TIPRL | c.410A>C p.D137A | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TLN1 | c.7124A>T p.K2375M | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TMEM200A | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2
- TMIE | c.213C>A p.I71= | Splice Region (SNP) | VAF 110/711 reads (15%) | called by muse, mutect2, varscan2
- TPCN2 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TRAF1 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRHR | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM29 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TRPA1 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPAN32 | c.424del p.R142Gfs*50 | Frame Shift Del (DEL) | VAF 56/224 reads (25%) | called by mutect2, pindel, varscan2
- TTI1 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 115/336 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTLL2 | c.1205T>A p.L402* | Nonsense Mutation (SNP) | VAF 45/158 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.55055A>C p.E18352A (on ENST00000591111; = p.E10928A on NM_003319.4) | Missense Mutation (SNP) | VAF 63/224 reads (28%) | PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TYRO3 | c.1700G>T p.R567M | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- UBASH3B | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UBN2 | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 166/489 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC13D | c.2959_2997del p.V987_L999del | In Frame Del (DEL) | VAF 41/286 reads (14%) | called by mutect2, pindel
- UNC80 | c.4033G>A p.A1345T | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- VCAN | c.1889G>T p.R630M | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- VSTM2A | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VSTM4 | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WWC3 | c.2439del p.W813Cfs*73 | Frame Shift Del (DEL) | VAF 59/97 reads (61%) | called by mutect2, pindel, varscan2
- XIRP1 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- YWHAG | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 34/555 reads (6%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.109); called by muse, mutect2
- ZAN | c.2088del p.T697Pfs*304 | Frame Shift Del (DEL) | VAF 122/479 reads (25%) | called by mutect2, pindel, varscan2
- ZBED6 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZBTB41 | c.1773-1G>A p.X591_splice | Splice Site (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- ZIM2 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF154 | c.137A>T p.N46I | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF205 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ZNF337 | c.897_901del p.R300* | Frame Shift Del (DEL) | VAF 45/330 reads (14%) | called by mutect2, pindel, varscan2
- ZNF343 | c.1511A>T p.Q504L | Missense Mutation (SNP) | VAF 101/292 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF776 | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF845 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 170/452 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZRANB1 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZSCAN5A | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 151/439 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZSWIM7 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- A1BG | c.844C>A p.R282= | Silent (SNP) | VAF 56/350 reads (16%) | catalogued as rs778614779, COSV54050019; called by muse, mutect2, varscan2
- ADAMTS13 | c.2844T>A p.A948= | Silent (SNP) | VAF 159/455 reads (35%) | called by muse, mutect2, varscan2
- AGPAT1 | c.60C>T p.F20= | Silent (SNP) | VAF 100/645 reads (16%) | catalogued as rs1259976228; called by muse, mutect2, varscan2
- AHNAK | c.15828C>T p.P5276= | Silent (SNP) | VAF 58/368 reads (16%) | catalogued as rs758787866, COSV99945467, COSV99949878; called by muse, varscan2
- AHNAK2 | c.9867G>T p.R3289= | Silent (SNP) | VAF 131/660 reads (20%) | catalogued as COSV60921144; called by muse, mutect2, varscan2
- ALS2 | c.396G>T p.P132= | Silent (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- ANKRD36B | c.270G>C p.L90= | Silent (SNP) | VAF 89/375 reads (24%) | called by muse, mutect2, varscan2
- ANTXRL | c.1143G>A p.K381= | Silent (SNP) | VAF 60/429 reads (14%) | catalogued as rs1330150649; called by muse, mutect2, varscan2
- AP002512.3 | c.516G>C p.A172= | Silent (SNP) | VAF 90/248 reads (36%) | called by muse, mutect2, varscan2
- AP2A2 | c.2731C>T p.L911= | Silent (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2
- APLP2 | c.915T>C p.D305= | Silent (SNP) | VAF 48/230 reads (21%) | called by muse, mutect2, varscan2
- APOB | c.2376C>T p.L792= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV99263648; called by muse, mutect2, varscan2
- ATP8B2 | c.2250G>A p.R750= (on ENST00000672630; = p.R717= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- ATR | c.2115A>G p.K705= | Silent (SNP) | VAF 43/119 reads (36%) | called by muse, mutect2, varscan2
- B3GAT1 | c.228C>A p.P76= | Silent (SNP) | VAF 60/256 reads (23%) | called by muse, mutect2, varscan2
- BCORL1 | c.4179G>T p.S1393= | Silent (SNP) | VAF 77/238 reads (32%) | called by muse, mutect2, varscan2
- BRSK2 | c.925C>T p.L309= | Silent (SNP) | VAF 113/423 reads (27%) | called by muse, mutect2, varscan2
- C1orf105 | c.438C>T p.G146= | Silent (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- CAMTA2 | c.2403T>C p.G801= | Silent (SNP) | VAF 22/597 reads (4%) | catalogued as rs1431954695; called by muse, mutect2
- CATSPERZ | c.54G>T p.S18= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- CCDC168 | c.4290G>T p.A1430= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- CD81 | c.579G>A p.K193= | Silent (SNP) | VAF 49/371 reads (13%) | called by muse, mutect2, varscan2
- CDH4 | c.561G>A p.P187= | Silent (SNP) | VAF 66/163 reads (40%) | catalogued as rs1253437195; called by muse, mutect2, varscan2
- COL22A1 | c.3810T>C p.G1270= | Silent (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- COL4A1 | c.4665C>A p.A1555= | Silent (SNP) | VAF 276/538 reads (51%) | called by muse, mutect2, varscan2
- COLCA2 | c.333A>G p.A111= | Silent (SNP) | VAF 52/305 reads (17%) | called by muse, mutect2, varscan2
- CRMP1 | c.558C>A p.T186= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV61483087; called by muse, mutect2, varscan2
- CYP2C19 | c.957C>T p.V319= | Silent (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- DGKI | c.42A>T p.P14= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- DHRS7C | c.759G>T p.V253= (on ENST00000330255 / NM_001220493.2; = p.V252= on NM_001105571.3) | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- DHRS7C | c.21G>C p.L7= | Silent (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- DMRT3 | c.12C>T p.Y4= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs991926296; called by muse, mutect2
- DOCK2 | c.4140C>G p.T1380= | Silent (SNP) | VAF 85/182 reads (47%) | called by muse, mutect2, varscan2
- EDIL3 | c.678T>A p.V226= | Silent (SNP) | VAF 116/256 reads (45%) | catalogued as COSV56891784; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2619C>A p.P873= | Silent (SNP) | VAF 112/301 reads (37%) | catalogued as rs376617168, COSV62570431; called by muse, mutect2, varscan2
- ENPP7 | c.175C>A p.R59= | Silent (SNP) | VAF 52/321 reads (16%) | called by muse, mutect2, varscan2
- ERCC6 | c.219G>A p.L73= | Silent (SNP) | VAF 50/411 reads (12%) | catalogued as rs777009906; called by muse, mutect2, varscan2
- EXOSC10 | c.45C>G p.T15= | Silent (SNP) | VAF 85/300 reads (28%) | called by muse, mutect2, varscan2
- FBXW10 | c.1137G>T p.L379= | Silent (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2
- FCRL2 | c.480G>T p.P160= | Silent (SNP) | VAF 116/460 reads (25%) | catalogued as COSV63834920; called by muse, mutect2, varscan2
- FEM1A | c.291C>T p.D97= | Silent (SNP) | VAF 83/300 reads (28%) | called by muse, mutect2, varscan2
- FLNC | c.900G>T p.V300= | Silent (SNP) | VAF 253/770 reads (33%) | called by muse, mutect2, varscan2
- FUS | c.876G>T p.L292= | Silent (SNP) | VAF 86/418 reads (21%) | called by muse, mutect2, varscan2
- GCM1 | c.297C>A p.A99= | Silent (SNP) | VAF 91/267 reads (34%) | called by muse, mutect2, varscan2
- GLYATL2 | c.471T>C p.D157= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- HOXC10 | c.603C>A p.T201= | Silent (SNP) | VAF 145/236 reads (61%) | catalogued as COSV100329129; called by muse, mutect2, varscan2
- HYDIN | c.8985C>T p.Y2995= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs760983916, COSV59258154; called by muse, mutect2
- IFNA4 | c.30C>A p.A10= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs199712722; called by muse, mutect2, varscan2
- ITPKB | c.1086G>T p.G362= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV55260641; called by muse, mutect2, varscan2
- KCND2 | c.723A>T p.T241= | Silent (SNP) | VAF 110/320 reads (34%) | catalogued as rs1341782874, COSV58606574; called by muse, mutect2, varscan2
- KLK9 | c.156C>A p.L52= | Silent (SNP) | VAF 145/361 reads (40%) | catalogued as rs1394447891; called by muse, mutect2, varscan2
- LAMC3 | c.4116C>T p.D1372= | Silent (SNP) | VAF 155/545 reads (28%) | called by muse, mutect2, varscan2
- LATS2 | c.924C>T p.A308= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs769212994; called by muse, mutect2, varscan2
- LGI1 | c.1296G>T p.V432= | Silent (SNP) | VAF 63/529 reads (12%) | called by muse, mutect2, varscan2
- LSM5 | c.27G>C p.P9= | Silent (SNP) | VAF 35/319 reads (11%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.3615C>T p.H1205= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as rs780089713; called by muse, mutect2, varscan2
- MEX3A | c.42G>T p.G14= | Silent (SNP) | VAF 202/592 reads (34%) | called by muse, varscan2
- MNDA | c.186A>G p.L62= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- MORC3 | c.2107C>T p.L703= | Silent (SNP) | VAF 44/441 reads (10%) | called by muse, mutect2, varscan2
- MRC1 | c.1053T>C p.V351= | Silent (SNP) | VAF 52/154 reads (34%) | called by muse, mutect2, varscan2
- MSMB | c.177A>T p.T59= | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- MYH11 | c.3129A>G p.L1043= | Silent (SNP) | VAF 121/374 reads (32%) | called by muse, mutect2, varscan2
- MYH3 | c.5553G>T p.L1851= | Silent (SNP) | VAF 199/549 reads (36%) | called by muse, mutect2, varscan2
- MYH4 | c.1257T>A p.T419= | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- MYO7B | c.2523C>A p.A841= | Silent (SNP) | VAF 129/453 reads (28%) | catalogued as COSV67349962; called by muse, mutect2, varscan2
- NALCN | c.1470T>A p.P490= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs774530102; called by muse, mutect2, varscan2
- NCCRP1 | c.222G>T p.L74= | Silent (SNP) | VAF 38/252 reads (15%) | called by muse, mutect2, varscan2
- NELFB | c.1044C>T p.D348= | Silent (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- NEURL4 | c.1911G>T p.T637= | Silent (SNP) | VAF 58/134 reads (43%) | called by muse, mutect2, varscan2
- NFATC3 | c.3180C>T p.P1060= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- NKX2-4 | c.99C>A p.G33= | Silent (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- NLRP3 | c.1311C>A p.T437= | Silent (SNP) | VAF 76/282 reads (27%) | called by muse, mutect2, varscan2
- NRIP3 | c.477C>A p.P159= | Silent (SNP) | VAF 118/270 reads (44%) | catalogued as COSV58469330; called by muse, mutect2, varscan2
- NTSR1 | c.1239C>T p.T413= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs142268215, COSV65139672; called by muse, mutect2, varscan2
- OR1S1 | c.867C>T p.V289= | Silent (SNP) | VAF 56/261 reads (21%) | catalogued as rs1565108895, COSV100515303; called by muse, mutect2, varscan2
- OR2T12 | c.660C>T p.L220= | Silent (SNP) | VAF 182/567 reads (32%) | catalogued as rs1473316901, COSV100527483, COSV58777869; called by muse, mutect2, varscan2
- OR4C6 | c.126T>G p.L42= | Silent (SNP) | VAF 46/227 reads (20%) | called by muse, mutect2, varscan2
- OR4F21 | c.783A>T p.P261= | Silent (SNP) | VAF 41/289 reads (14%) | called by muse, mutect2, varscan2
- OR4K17 | c.253T>C p.L85= | Silent (SNP) | VAF 37/216 reads (17%) | called by muse, mutect2, varscan2
- OR4L1 | c.141C>A p.V47= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- OR4Q3 | c.513A>T p.L171= | Silent (SNP) | VAF 56/464 reads (12%) | called by muse, varscan2
- OR5F1 | c.693G>T p.G231= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV53545197, COSV99558774; called by muse, mutect2, varscan2
- OR5L2 | c.159T>A p.S53= | Silent (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- OR8G1 | c.387C>T p.P129= | Silent (SNP) | VAF 93/255 reads (36%) | catalogued as COSV100422578; called by muse, mutect2, varscan2
- OR8H2 | c.558T>A p.A186= | Silent (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- OR8H2 | c.802T>C p.L268= | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- PCK1 | c.1116C>A p.G372= | Silent (SNP) | VAF 214/530 reads (40%) | called by muse, varscan2
- PKD1 | c.11397G>A p.A3799= (on ENST00000262304 / NM_001009944.3; = p.A3798= on NM_000296.4) | Silent (SNP) | VAF 153/605 reads (25%) | catalogued as rs753956366; called by muse, mutect2, varscan2
- PLCL2 | c.2226C>A p.A742= (on ENST00000615277 / NM_001144382.2; = p.A616= on NM_015184.5) | Silent (SNP) | VAF 46/392 reads (12%) | called by muse, mutect2, varscan2
- POM121L12 | c.366G>T p.G122= | Silent (SNP) | VAF 148/394 reads (38%) | catalogued as COSV101374976, COSV101375003; called by muse, mutect2, varscan2
- PRAMEF10 | c.513C>A p.I171= | Silent (SNP) | VAF 60/329 reads (18%) | catalogued as COSV99339190; called by muse, mutect2, varscan2
- PRKAR1B | c.201G>A p.A67= | Silent (SNP) | VAF 124/378 reads (33%) | catalogued as rs147480983; called by muse, mutect2, varscan2
- PYGL | c.1953A>T p.V651= | Silent (SNP) | VAF 108/497 reads (22%) | called by muse, mutect2, varscan2
- RAD54L2 | c.465G>T p.P155= | Silent (SNP) | VAF 72/189 reads (38%) | catalogued as rs771145134, COSV56580062; called by muse, mutect2, varscan2
- RDH13 | c.618C>T p.A206= (on ENST00000415061 / NM_001145971.2; = p.A135= on NM_138412.4) | Silent (SNP) | VAF 50/355 reads (14%) | called by muse, mutect2, varscan2
- ROR1 | c.33G>T p.P11= | Silent (SNP) | VAF 58/105 reads (55%) | called by muse, mutect2, varscan2
- RYR2 | c.11631C>T p.Y3877= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- SACS | c.10731A>G p.T3577= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs759287298; called by muse, mutect2, varscan2
- SHANK2 | c.1719A>T p.G573= | Silent (SNP) | VAF 113/338 reads (33%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.438C>A p.P146= | Silent (SNP) | VAF 32/450 reads (7%) | called by muse, mutect2
- SLC10A5 | c.1065T>C p.A355= | Silent (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- SLC4A3 | c.3567G>T p.V1189= | Silent (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- SLC9A8 | c.531T>A p.G177= | Silent (SNP) | VAF 44/185 reads (24%) | called by muse, mutect2, varscan2
- SMC6 | c.2617C>A p.R873= | Silent (SNP) | VAF 69/497 reads (14%) | catalogued as COSV61175831; called by muse, mutect2, varscan2
- SMIM24 | c.45C>A p.L15= | Silent (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- SNX32 | c.1209T>A p.P403= | Silent (SNP) | VAF 101/268 reads (38%) | catalogued as rs770227682; called by muse, mutect2, varscan2
- SPHKAP | c.3880C>A p.R1294= | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- STAT1 | c.1251C>A p.T417= | Silent (SNP) | VAF 36/386 reads (9%) | called by muse, mutect2
- TACC2 | c.7086G>T p.L2362= (on ENST00000334433; = p.L440= on NM_006997.4) | Silent (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- TAS1R2 | c.2355G>C p.G785= | Silent (SNP) | VAF 194/1074 reads (18%) | catalogued as rs534929855; called by muse, mutect2, varscan2
- TCERG1L | c.408C>A p.P136= | Silent (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- TLL2 | c.1602G>A p.L534= | Silent (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- TMEM218 | c.318G>T p.P106= | Silent (SNP) | VAF 62/148 reads (42%) | called by muse, mutect2, varscan2
- TNS4 | c.2127G>T p.L709= | Silent (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1297C>A p.R433= | Silent (SNP) | VAF 46/198 reads (23%) | called by muse, mutect2, varscan2
- TRBJ2-2 | c.52G>T p.*18= | Silent (SNP) | VAF 75/297 reads (25%) | called by muse, mutect2, varscan2
- UGT2B15 | c.1542G>C p.L514= | Silent (SNP) | VAF 67/224 reads (30%) | called by muse, mutect2, varscan2
- UGT3A1 | c.123G>T p.R41= | Silent (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2, varscan2
- UTF1 | c.396G>A p.P132= | Silent (SNP) | VAF 71/584 reads (12%) | called by muse, mutect2, varscan2
- YWHAB | c.174C>G p.R58= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- ZBTB41 | c.384G>T p.L128= | Silent (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7996C>A p.R2666= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV50773918; called by muse, mutect2, varscan2
- ZNF135 | c.87G>A p.G29= | Silent (SNP) | VAF 82/211 reads (39%) | catalogued as rs777568005; called by muse, mutect2
- ZNF232 | c.195C>T p.T65= | Silent (SNP) | VAF 119/605 reads (20%) | catalogued as rs531992462; called by muse, mutect2, varscan2
- ZNF236 | c.588G>T p.T196= | Silent (SNP) | VAF 17/247 reads (7%) | called by muse, mutect2
- AC008080.1 | n.679C>T | RNA (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- AC092818.1 | n.447C>A | RNA (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- ACAD10 | c.2818-253A>G | Intron (SNP) | VAF 7/149 reads (5%) | catalogued as rs1331689400; called by muse, mutect2
- AF121898.1 | n.205+26747C>A | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- AL359195.2 | n.3182del | RNA (DEL) | VAF 90/685 reads (13%) | called by mutect2, varscan2
- ALDH1L1 | c.2653+53C>A | Intron (SNP) | VAF 81/249 reads (33%) | called by muse, mutect2, varscan2
- ALOX15B | c.-10G>T | 5'UTR (SNP) | VAF 56/137 reads (41%) | called by muse, mutect2, varscan2
- APOOP5 | chr16:59751989 G>T | 3'Flank (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.2172-401A>T | Intron (SNP) | VAF 84/220 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915820 C>T | 5'Flank (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- BTD | chr3:15601568 C>A | 5'Flank (SNP) | VAF 62/423 reads (15%) | catalogued as COSV100329509; called by muse, mutect2, varscan2
- C11orf96 | chr11:43943483 C>T | 3'Flank (SNP) | VAF 58/434 reads (13%) | called by muse, mutect2, varscan2
- C16orf82 | c.-124C>T | 5'UTR (SNP) | VAF 41/150 reads (27%) | catalogued as rs779048114; called by muse, mutect2, varscan2
- C4orf50 | c.-423C>T | 5'UTR (SNP) | VAF 47/202 reads (23%) | called by muse, mutect2, varscan2
- CAMKK1 | c.-13C>G | 5'UTR (SNP) | VAF 32/156 reads (21%) | called by muse, mutect2, varscan2
- CARF | c.1332-851C>A | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- CBLN1 | c.265-22C>T | Intron (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- CEMIP | c.1797+245G>A | Intron (SNP) | VAF 45/269 reads (17%) | called by muse, mutect2, varscan2
- CFAP157 | c.*1423G>A | 3'UTR (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
- CHRND | c.*369C>A | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- CLEC7A | c.202+351C>T | Intron (SNP) | VAF 69/147 reads (47%) | catalogued as rs1444298280; called by muse, mutect2, varscan2
- CNTN4 | c.2092+12C>A | Intron (SNP) | VAF 126/519 reads (24%) | called by muse, mutect2, varscan2
- CORIN | c.2068+46C>T | Intron (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1124+9046A>T | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- DLL1 | c.-894C>A | 5'UTR (SNP) | VAF 96/441 reads (22%) | called by muse, mutect2, varscan2
- DMKN | c.1039-198G>T | Intron (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- DMKN | c.1039-199G>T | Intron (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- DNAH14 | c.5585-965C>T | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- DRD2 | c.*41C>A | 3'UTR (SNP) | VAF 82/326 reads (25%) | called by muse, mutect2
- FAM20A | c.*1885A>G | 3'UTR (SNP) | VAF 73/339 reads (22%) | called by muse, mutect2, varscan2
- FOSB | c.447+71G>T | Intron (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.862G>T | RNA (SNP) | VAF 97/256 reads (38%) | called by muse, mutect2, varscan2
- GABRG3 | c.271-55213T>A | Intron (SNP) | VAF 88/167 reads (53%) | called by muse, mutect2, varscan2
- GOLGA6L10 | c.*4C>A | 3'UTR (SNP) | VAF 249/1350 reads (18%) | called by muse, mutect2, varscan2
- GRK6 | c.-40C>T | 5'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- GRM4 | c.736+12G>C | Intron (SNP) | VAF 93/262 reads (35%) | called by muse, mutect2, varscan2
- HDAC4 | c.*70G>T | 3'UTR (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.124C>A | RNA (SNP) | VAF 243/602 reads (40%) | called by muse, mutect2, varscan2
- IPO8 | c.640-310G>T | Intron (SNP) | VAF 76/154 reads (49%) | catalogued as rs1323607675; called by muse, mutect2, varscan2
- LAMB4 | c.2124+1063T>A | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- LRBA | c.7726+77del | Intron (DEL) | VAF 42/179 reads (23%) | called by mutect2, pindel, varscan2
- LSS | c.-20C>T | 5'UTR (SNP) | VAF 74/477 reads (16%) | catalogued as rs751723086; called by muse, mutect2, varscan2
- MACF1 | c.220+21189G>T | Intron (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- MAP2 | c.455-1888G>C | Intron (SNP) | VAF 79/246 reads (32%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+2479C>G | Intron (SNP) | VAF 36/225 reads (16%) | called by muse, mutect2, varscan2
- MAST4 | c.1591+11G>T | Intron (SNP) | VAF 85/191 reads (45%) | called by muse, mutect2, varscan2
- MGAM2 | c.3183-20G>T | Intron (SNP) | VAF 147/511 reads (29%) | called by muse, mutect2, varscan2
- MIA3 | c.4874+14G>C | Intron (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- MPP2 | chr17:43909587 C>G | 5'Flank (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- MST1L | n.350C>G | RNA (SNP) | VAF 74/417 reads (18%) | catalogued as rs764969968; called by muse, mutect2, varscan2
- NAPSB | n.888G>T | RNA (SNP) | VAF 43/353 reads (12%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+55101C>A | Intron (SNP) | VAF 49/94 reads (52%) | called by muse, mutect2, varscan2
- NLRC5 | c.4154+253G>A | Intron (SNP) | VAF 16/90 reads (18%) | catalogued as rs1278243773; called by muse, varscan2
- NPHP1 | c.1927-11T>A | Intron (SNP) | VAF 57/359 reads (16%) | called by muse, mutect2, varscan2
- OGFOD3 | c.824-1926G>C | Intron (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- PCDHB6 | chr5:141157440 G>C | 3'Flank (SNP) | VAF 378/734 reads (51%) | called by muse, mutect2, varscan2
- PDE4B | c.635-48G>C | Intron (SNP) | VAF 68/302 reads (23%) | called by muse, mutect2, varscan2
- PRPF40B | chr12:49623512 C>A | 5'Flank (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- PTPRM | c.664-2244T>C | Intron (SNP) | VAF 52/249 reads (21%) | called by muse, mutect2, varscan2
- RAD51D | c.*606G>T | 3'UTR (SNP) | VAF 157/362 reads (43%) | called by muse, mutect2, varscan2
- RARA | c.*80C>G | 3'UTR (SNP) | VAF 54/149 reads (36%) | called by muse, mutect2, varscan2
- RHOJ | c.-11G>T | 5'UTR (SNP) | VAF 69/340 reads (20%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2269T>G | RNA (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.384T>A | RNA (SNP) | VAF 228/677 reads (34%) | called by muse, mutect2, varscan2
- RPL7A | c.3+28A>G | Intron (SNP) | VAF 64/180 reads (36%) | catalogued as rs200194265; called by muse, mutect2, varscan2
- SGK1 | c.-12C>A | 5'UTR (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- SLC7A8 | c.508+10085T>C | Intron (SNP) | VAF 57/318 reads (18%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-47949T>G | Intron (SNP) | VAF 11/131 reads (8%) | catalogued as COSV67440776, COSV67448586; called by muse, mutect2
- SMPD1 | c.-40del | 5'UTR (DEL) | VAF 84/185 reads (45%) | called by mutect2, varscan2
- SPATA8 | n.804C>A | RNA (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- SPINK2 | c.55+90G>T | Intron (SNP) | VAF 123/274 reads (45%) | called by muse, mutect2, varscan2
- SSPOP | n.4730C>G | RNA (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- STXBP6 | c.452-62G>T | Intron (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- SUGCT | c.1089+2729C>T | Intron (SNP) | VAF 86/299 reads (29%) | catalogued as rs904985758, COSV59338265; called by muse, mutect2, varscan2
- TAFA4 | c.*5G>A | 3'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- TCF25 | c.548+24G>T | Intron (SNP) | VAF 161/620 reads (26%) | called by muse, mutect2, varscan2
- TMEM139 | c.*2T>C | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- TMPRSS3 | c.782+10G>T | Intron (SNP) | VAF 138/613 reads (23%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.782+9T>C | Intron (SNP) | VAF 138/619 reads (22%) | called by muse, mutect2, varscan2
- TPRXL | n.887A>T | RNA (SNP) | VAF 183/561 reads (33%) | called by muse, mutect2, varscan2
- TPTE | c.-2G>C | 5'UTR (SNP) | VAF 37/855 reads (4%) | called by muse, mutect2
- TRIOBP | c.5322+5339G>T | Intron (SNP) | VAF 68/112 reads (61%) | called by muse, varscan2
- TSPAN32 | c.354+558G>C | Intron (SNP) | VAF 67/138 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.10360+2763T>C | Intron (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- TTR | c.*16G>T | 3'UTR (SNP) | VAF 147/541 reads (27%) | called by muse, mutect2, varscan2
- ZNF99 | c.*708T>C | 3'UTR (SNP) | VAF 100/236 reads (42%) | catalogued as rs372760670; called by muse, varscan2
